Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AC6N, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AC6N-TTM1-A (Metastatic).

[page 1 of 8]
RESULT REVIEW REPORT

Performing Facility: [REDACTED]

Printed: [REDACTED]

Printed By: [REDACTED]

MD

Verifying Provider:

Primary Care Physician: [REDACTED]

MD

Report Name: PATH-Cytology-Non Gyn

Service Date: [REDACTED]

+0

CYTOPATHOLOGY REPORT

Collect Date [REDACTED] +0

Received: [REDACTED] +0

Reported: [REDACTED] +3

Final Cytologic Diagnosis

Pleural Fluid:

Satisfactory for evaluation.

MALIGNANT CELLS PRESENT

Consistent with bronchogenic adenocarcinoma.

Electronically Signed Out

Source of Specimen(s)

Pleural Fluid

Gross Description

Received one liter of cloudy yellow fluid to make one thin cell layer preparation and one cellblock.

Comment(s)

The tumor cells stain strongly positive for Ber-EP4 and TTF-1 (consistent with bronchogenic adenocarcinoma). Staining is not observed for estrogen receptor protein or calretinin.

[page 2 of 8]
RESULT REVIEW REPORT

Printed:
Printed By:

MD

Verifying Provider:

MD
Service Date:

+4

SURGICAL PATHOLOGY REPORT

Case #:

Surgery Date: +4
Received: +4
Reported: +7

Final Pathologic Diagnosis

A. Epicardial mass, biopsy:

Poorly differentiated adenocarcinoma, with immunophenotypic features consistent with lung primary.

B. Pericardial mass, biopsy:

Poorly differentiated adenocarcinoma, with immunophenotypic features consistent with lung primary.

Electronically Signed Out

Pre-Operative Diagnosis
Right pleural effusionIntraoperative Diagnosis
FROZEN SECTION: 4 Positive for malignancy. 4

Gross Description

A. Labeled 3 epicardial mass biopsy 4 on Received fresh is a tan tissue fragment measuring 0.7 x 0.5 x 0.2 cm. Entirely submitted for frozen section diagnosis in one cassette.

B. Labeled 3 pericardial biopsy 4 on Received in formalin are multiple tan tissue fragments measuring 2.0 x 1.5 x 0.6 cm. in aggregate.

[page 3 of 8]
Printed:
Printed By

MD

Verifying Provider:

MD
Service Date:

+4

Entirely submitted in two cassettes.

Microscopic Description
A. Sections show fibrous tissue infiltrated by small poorly formed glands and nests of cells with abundant cytoplasm, vesicular nuclei and distinct nucleoli. Occasional mitotic figures are seen. No necrosis is present.

B. Sections show fibrous tissue infiltrated by small poorly formed glands and nests of cells with abundant cytoplasm, vesicular nuclei and distinct nucleoli. Occasional mitotic figures are seen. No necrosis is present. By immunohistochemistry, the tumor shows the following phenotype: pankeratin (+), CK7 (+), CK20 (focal +), Ber-EP4 (+), calretinin (-), TTF-1 (+), thyroglobulin (-), and GCDFP-15 (-).

Analyte-specific reagent(s)/antibody(ies) were developed for immunohistochemistry and their performance characteristics determined by an outside vendor. Pertinent diagnostic performance characteristics were then verified by [REDACTED] Lab prior to use. These reagents/antibodies have not been cleared or approved by the FDA, however, the FDA has determined that such clearance or approval is not necessary. This test was used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[page 4 of 8]
RESULT REVIEW REPORT

Performing Facility: [REDACTED]

Label ID: RESULTS [REDACTED]

Printed: [REDACTED]

Printed By: [REDACTED]

Ordering Provider: [REDACTED]

MD

Verifying Provider: [REDACTED]

MD

Primary Care Physician: [REDACTED]

MD

Report Name:CT-Chest With Contrast

Service Date: [REDACTED]

+2

DICTATING PHYSICIAN: [REDACTED]

EXAM: CT of the chest with contrast [REDACTED]

+2

COMPARISON: Outside CT of the chest [REDACTED]

-1

HISTORY: 56-year-old with reported lymphoma. Patient complains of upper extremity pain and neck tightness. Right pleural effusion.

PROCEDURE: Enhanced CT of the chest obtained from the thoracic inlet to the diaphragm with 5 mm slice acquisition and 5 mm lung window reconstructions using 100 mL Isovue-300 IV. No contrast reaction. Coronal reformatted images were available for evaluation.

FINDINGS: Lung windows demonstrate no abnormalities of the visualized trachea. Moderate right pleural effusion. Calcified right lower lobe granuloma. Parenchymal opacity involving the right costophrenic angle may represent atelectasis. Mild bilateral dependent atelectasis. No consolidation or pneumothorax. 4 mm right lower lobe indeterminate pulmonary nodule best seen on image #42, series 3. There is a right hilar mass measuring 3.4 x 1.7 cm best seen on image #29, series 3.

Mediastinal windows demonstrate no abnormalities of visualized thyroid gland. Moderate pericardial effusion. No cardiomegaly or coronary artery calcification. The pulmonary artery is not enlarged. Atherosclerotic calcification of a nonaneurysmal thoracic aorta. There is a heterogeneous mediastinal mass measuring 3.5 x 3.7 cm in greatest dimension the with mass-effect and compression of the right pulmonary artery. There is complete opacification of the superior vena cava as well as the internal jugular and brachiocephalic veins compatible with thrombus. Tumor infiltration cannot be excluded. There are diffuse venous collaterals throughout the upper extremities. There is also prominence of the azygos system. The esophagus is unremarkable.

Bone windows demonstrate degenerative change of the thoracic spine. No destructive osseous lesions.

Limited images of the upper abdomen demonstrate heterogeneous enhancement of the liver which may be secondary to collateral flow from obstructed superior vena cava. There are multiple low density nodules within the right and left hepatic lobes, the largest of these measuring 2.6 cm. There is also a 0.8 cm left adrenal nodule. These lesions are concerning for neoplasm. The visualized gallbladder is unremarkable. The upper pole kidneys are normal. The right adrenal gland is normal. Calcified splenic granulomas. The visualized

[page 5 of 8]
RESULT REVIEW REPORT

Performing Facility:

Label ID: RESULTS-

Printed:

Printed By:

Ordering Provider:

MD

Verifying Provider:

MD

Primary Care Physician:

MD

Report Name:CT-Chest With Contrast

Service Date:

+10

pancreas is unremarkable. Scattered enlarged periaortic lymph nodes; the largest of these measuring 1.5 cm in short axis dimension.

IMPRESSION:

1. Heterogeneous 3.7 x 3.3 cm mediastinal mass produces mass-effect upon the superior vena cava as well as the right pulmonary artery. Tumor infiltration cannot be excluded.
2. Complete opacification of the internal jugular veins, brachiocephalic veins, and superior vena cava likely with thrombus. Tumor infiltration cannot be excluded. Prominence of the azygos system and upper extremity collaterals. These findings are concerning for superior vena cava syndrome.
3. Scattered hypodense lesions throughout the hepatic lobes, the largest of these measuring 2.6 cm. These lesions are concerning for metastatic disease or neoplasm. Recommend correlation with three-phase CT of the liver for further evaluation.
4. 0.8 cm left adrenal nodule is indeterminate. Recommend attention at three-phase liver CT.
5. Diffuse periaortic lymphadenopathy.
6. Moderate right pleural effusion.
7. 3.4 cm right parahilar mass is concerning for neoplasm.
8. 0.4 cm indeterminate noncalcified pulmonary nodule in the anterior basal segment of the right lower lobe. Recommend attention at follow-up.
9. Moderate pericardial effusion.

+3

I, as the teaching physician, personally reviewed the radiologic study and concur with this interpretation.

[page 6 of 8]
EXAM DATE: [REDACTED] +112

CT ABDOMEN W/WO CONTRAST; CTPELVIS

W/WO CONTRAST; CT THORAX W/WO CONTRAST,

CLINICAL INDICATION:

MASS IN RIGHT LUNG. PATIENT IS UNDERGOING CHEMO. FOLLOW-UP EXAM [REDACTED]

CT THORAX:

Axial and coronal images were obtained from apices extending down to level of domes of diaphragm with and without intravenous administration of contrast material.

Comparison was made with the previous study of [REDACTED] +70

Again noted is right paratracheal/superior mediastinal mass with tiny calcifications. This mass is lobulated with central low density areas. Mass is causing slight compression at right pulmonary artery. No significant decrease in size of superior mediastinal mass. Again seen is obstruction of superior vena cava/occlusion with reidentification of abundant intercostal, intramammary and several subcutaneous and umbilical collateral vessels. Somewhat decrease in amount of right pleural effusion since previous study. Right middle lobe atelectasis is resolving. However, right lower lobe compression atelectasis due to pleural effusion is again seen. Calcified subcarinal lymph nodes are reidentified. Right hilar lymphadenopathy is again noted. No pleural effusion in left lung. No pericardial effusion. Osteoblastic metastatic changes in dorsal spine are again noted.

IMPRESSION:

1. DECREASE IN AMOUNT OF RIGHT PLEURAL EFFUSION SINCE PREVIOUS STUDY. PREVIOUSLY SEEN ATELECTASIS OF RIGHT MIDDLE LOBE IS IMPROVING. HOWEVER, ATELECTASIS OF RIGHT LOWER LOBE DUE TO PLEURAL EFFUSION IS AGAIN SEEN.

2. NO CHANGE IN SIZE OF MEDIASTINAL LOBULATED MASS.

3. SUPERIOR VENA CAVA OBSTRUCTION WITHOUT ANY CHANGE SINCE PREVIOUS STUDY.

CC: [REDACTED] RADIOLOGY

Additional copy

NAME: [REDACTED]

EXAM DATE: [REDACTED]

CT REPORT

+102

[page 7 of 8]
CT REPORT CONT

4. OSTEOLASTIC CHANGES IN MID DORSAL SPINE REPRESENTING METASTASIS WITHOUT ANY CHANGE SINCE PREVIOUS STUDY.

CT SCAN ABDOMEN AND PELVIS:

Axial and coronal images were obtained with and without intravenous administration of contrast material. Oral administration of contrast material was used.

Comparison was made with the previous study of [REDACTED] +70

Again noted is a 3.0 x 2.6 cm minimally peripherally enhancing mass in left lobe of liver, probably representing metastasis. No new lesion in liver since previous study. Tiny calcifications are seen in spleen representing chronic granulomatous disease. However there are no abnormal contrast-enhancing lesions. No abnormal finding in gallbladder or pancreas. No right adrenal mass lesion. Again noted is a 1.3 cm low-density left adrenal mass, probably representing adenoma versus metastasis. Both kidneys demonstrate normal excretory function and enhancement without hydronephrosis or obstruction. Again noted are subcentimeter retroperitoneal lymph nodes without increase in size since previous study. No abnormal fluid collection. No large or small bowel obstruction. Again noted are intercostal and umbilical collateral vessels due to superior vena cava obstruction.

In pelvis reidentified is oval-shaped heterogeneous mass measuring 9.0 x 5.5 cm with several low-density areas along with tiny calcifications, probably representing fibroid with differential diagnosis of ovarian tumor. Again noted is a 1.6 cm low-density left adnexal mass representing ovarian cyst. No fluid collection or lymphadenopathy. No intrinsic abnormality of bladder. No abnormal finding in inguinal region. Mild degenerative changes of lumbar spine are noted with degenerative disk disease at L5 - S1.

IMPRESSION: +70

1. STABLE EXAMINATION SINCE PREVIOUS STUDY OF [REDACTED] WITH REIDENTIFICATION OF 3.0 X 2.6 CM

LOW-DENSITY MINIMALLY PERIPHERALLY ENHANCING MASS IN LEFT LOBE OF LIVER REPRESENTING METASTASIS WITH DIFFERENTIAL DIAGNOSIS OF OTHER SPACE-OCCUPYING MASS LESION IN LIVER.

2. SMALL SUBCENTIMETER RETROPERITONEAL LYMPH NODES, PROBABLY REPRESENTING METASTATIC LYMPH NODES.

3. LARGE LOBULATED PELVIC MASS WITH HETEROGENEOUS ENHANCEMENT AND LOWER DENSITY AREAS AND TINY

CC: [REDACTED] RADIOLOGY

Additional copy

CT REPORT

EXAM DATE: [REDACTED]

+112

[page 8 of 8]
PATIENT NAME: [REDACTED]

EXAM DATE: [REDACTED] +2001

PATIENT LOCATION: [REDACTED]

PATIENT STATUS: [REDACTED]

EXAM # [REDACTED], MRI MRI BRAIN/W/O CONTR W/ADD SEQ,

Examination: MRI brain [REDACTED] +2001

Clinical Indication: Carcinoma of the lung diagnosed 5 years ago. Nausea and vomiting. Last chemo treatment four weeks ago.

Comparison: CT head [REDACTED] +1185

MRI of the brain without and with IV contrast using 1.5 Tesla system. Multiecho multiplanar study is performed.

A space-occupying lesion is noted in the medial right cerebellum which on postcontrast images measures 3.2 x 3.2 x 3.2 cm. Heterogeneous enhancement. High signal intensity areas noted at the periphery of the mass on precontrast T1 sequence suggesting possible hemorrhagic component. There is noted an additional small lesion measuring about 1 cm lateral part of the right cerebellum which is mildly hyperintense on precontrast T1. This does not show any enhancement with contrast. No signal drop noted on blood sensitive sequence in this smaller lesion. The larger lesion is showing mass effect on the brainstem and fourth ventricle which are displaced to the left. There may be minimal dilatation of the third and lateral ventricles. Periventricular and deep white matter T2 hyperintensities noted related to microangiopathy. No abnormal supratentorial enhancing space-occupying lesions. No supratentorial midline shift. No extraaxial collection. Normal vascular flow void. Minimal mucosal edema in the maxillary and ethmoid sinuses.

Right cerebellar tonsil slightly displaced downwards.

IMPRESSION:

3.2 cm right cerebellar mass with surrounding edema and mass effect on the brainstem and fourth ventricle and suspected mild hydrocephalus. The lesion may represent metastatic focus in this patient with history of lung carcinoma. The other possibility could be a primary brain tumor.

*** THIS IS AN ELECTRONICALLY VERIFIED REPORT ***

CC [REDACTED]

Additional copy

DICTATION DATE/TIME: [REDACTED]

TECHNOLOGIST: [REDACTED]

TRANSCRIBED DATE/TIME: [REDACTED]

TRANSCRIPTIONIST: [REDACTED]

PRINTED DATE/TIME: [REDACTED]

NAME: [REDACTED]

ACC: [REDACTED]
EXAM DATE: [REDACTED]

STATUS: [REDACTED]
+2001 PAGE: 1

RADIOLOGY REPORT

Source: NCI Genomic Data Commons file 617c902f-c168-462f-90c6-caf042032bbe (ER0078 ER-AC6N Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).